Surgical pathology report (de-identified scan), TCGA case TCGA-IB-AAUT, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-AAUT-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Time Received

Time Transmitted

Ordering Provider

Relevant Information

Location

Copied To

Report Patient

Name

Demographics (for
verification purposes)

Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Renorr*****

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

Specimen Description

A. Gallbladder

B. Lymph node #8

C. Whipple

D. Pancreas margin

E. Small bowel mass

Clinical Information

Infectious patient: No

Immunocompromised: No

History of neoplasm: Yes

Pancreatic mass.

1ED-0-3
(Carcinoma), collected 8480/3
Site: ^{cell} Pancreas head C25.0
^{path} Pancreas NOS C25.9
QW 5/20/14

Per TSS, TCGA tumor sample from
Pancreatic head. bcr

Diagnosis

A. Gallbladder, Cholecystectomy:

- Chronic cholecystitis.

B. Lymph node, Number 8, Excision:

- A single lymph node negative for malignancy (0/1).

C. Duodenum and Pancreas, Whipple Procedure:

- Colloid carcinoma, 3.2 cm, confined to the pancreas;

- Lymphovascular invasion present;

- Perineural invasion present;

- Uncinate and vascular bed resection margins positive;

- Metastatic colloid carcinoma to seven of nine

lymph nodes (7/9);

D. Pancreatic Margin, Biopsy:

- A single lymph node and vascularized fibrofatty tissue
negative for malignancy (0/1).

E. Soft Tissue, Small Bowel Wall, Resection:

Benign fibrous nodule (See microscopic description).

Reported by:

Electronically signed by:

Verified:

Synoptic Report

HISTOLOGIC TYPE:

Mucinous noncystic carcinoma

Colloid Carcinoma

HISTOLOGIC GRADE

MICROSCOPIC TUMOR EXTENSION:

[page 2 of 3]
Tumor is confined to pancreas

MARGINS:

Distance of invasive carcinoma from closest margin: 0.2 mm

Specified margin: Uncinate

Margin(s) involved by invasive carcinoma

Uncinate process (retroperitoneal) margin (nonperitonealized surface of the uncinate process)

Vascular bed margin.

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT2: Tumor limited to the pancreas, more than 2 cm in greatest dimension

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 11

Number involved: 7

DISTANT METASTASIS (pM):

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS:

Chronic pancreatitis

Gross Description

Received are specimen containers A to E. All requisitions and specimen containers are labelled with the patient's name, . The cassettes and identifiers are labelled with the Surgica.

A. Specimen is received fresh, subsequently placed into formalin. The container is designated "A. Gallbladder". The specimen consists of a purple-tan gallbladder measuring 8.5 x 4.5 x 3.0 cm. Serosal surface is smooth and slightly congested. Cystic duct is patent. The lumen contains green watery bile. Calculi are not identified. Cystic duct lymph node is not identified. The mucosa is green and slightly granular. The wall averages 0.2 cm in thickness. Representative sections are submitted in one cassette.

B. Specimen is received fresh, subsequently placed into formalin. The container is designated "B. Lymph node #8". The specimen consists of an irregular portion of fibrofatty tissue measuring 2.8 x 1.3 x 0.8 cm. A possible lymph node is identified measuring 2.0 x 1.0 x 0.8 cm. The possible lymph node is bisected, submitted in toto in one cassette.

C. Specimen is received fresh, subsequently placed into formalin. The container is designated "C. Whipple's". The specimen consists of a portion of duodenum and attached pancreas. The duodenum measures 22.0 cm in length and averages 7.0 cm in circumference. There is little to no attached mesentery and the serosal surface is grey-tan. The proximal 10.0 cm of the duodenal mucosa is tan and grossly unremarkable. There is a sharp demarcation from unremarkable to congested mucosa for the remaining length, 14.0 cm. The pancreas measures 6.0 x 5.0 x 2.5 cm. The margins are painted as follows: body is inked blue, vessel bed orange, and uncinate margin green. The pancreas is serially sectioned. Cut surface reveals a mucinous ill-defined tan lesion measuring 3.2 x 3.0 x 3.0 cm, and comes within 1.3 cm to the body margin and grossly comes within less than 0.1 cm to the vessel bed and uncinate margins. The lesion abuts the common bile duct. Remaining pancreatic parenchyma appears grossly unremarkable. The common bile duct is present and measures 5.0 cm in length and becomes narrowed at the ampulla with thickening of the wall. Circumference ranges from 0.5 cm at the ampulla and 2.0 cm at the common bile duct margin. Mucosa appears grossly unremarkable. Three possible lymph nodes ranging in size from 0.8 x 0.8 x 0.3 cm to 1.5 x 0.8 x 0.8 cm are palpated from the peripancreatic soft tissue. Sections are submitted as follows:

- C1 - shave section, common bile duct margin.
- C2 - proximal margin, bisected.
- C3-4 - representative sections from distal margin.
- C5 - representative section from grossly normal appearing duodenum to congested mucosa.
- C6 - shave section from body margin.
- C7-8 - lesion in relation to uncinate margin and peripancreatic fat.
- C9-10 - lesion in relation to vessel bed margin.
- C11 - common bile duct thickened area.
- C12 - longitudinal sections of ampulla and common bile duct.
- C13 - one possible lymph node.
- C14-15 - one possible lymph node bisected each.

D. The specimen consists of soft tissue measuring 1.4 x 0.7 x 0.4 cm, with cauterized surface. Submitted in toto.

[page 3 of 3]
Specimen is received fresh, subsequently placed into formalin. The container is designated "D. Pancreas margin".

E. Specimen is received fresh, subsequently placed into formalin. The container is designated "E. Small bowel mass". The specimen consists of a tan to hemorrhagic nodule with attached soft tissue, measuring 1.3 x 0.7 x 0.5 cm. The specimen is bisected, submitted in toto in one cassette.

Frozen Section Diagnosis

D. Pancreas margin:

- No tumor identified.

Reported by:

Microscopic Description

E. There is a subserosal nodule that is predominantly fibrotic with stromal calcifications. CD117 is negative and so is S100. CD34 highlights blood vessels.

C. Best Tumor Block : C8 (but still requires macrodissection since the tumor has a hypocellular nature and there is a lymph node in the same section); Best normal tissue block: C4.

Pathologist Comment

C. Tumor involves the wall of the common bile duct close to the ampulla but does not involve the ampulla proper. The uncinate and vascular bed margins show cauterized mucinous cystic nodules that are acellular but represent tumor. Margin status was discussed with Dr. who reviewed slide C9 and C12.

Accession Number

Encounter Number

Patient Location

*Site discrepancy - path indicates pancreas, on
pan TSS - imaging support pancreas head.*

Primary Tumor Site Discrepancy pancreas, N65	☒	

Source: NCI Genomic Data Commons file 5ec5f882-6970-4b38-92e1-b91b249ebbd7 (TCGA-IB-AAUT.1E0670AB-5722-4D62-9F92-20523E4FDAE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).